Somatic mutation profile of tumor specimen TCGA-DD-A11A-01A (aliquot TCGA-DD-A11A-01A-11D-A12Z-10) from TCGA case TCGA-DD-A11A, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 67.5 years (24,646 days).
Specimen TCGA-DD-A11A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a6bd1a5-7fb9-4626-8a85-3cc57c7d85cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A11A-10A (Blood Derived Normal), aliquot TCGA-DD-A11A-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c941954f-f289-4af2-9907-571ad3108ee7

The open-access MAF lists 144 somatic variants for this specimen: 106 protein-altering or splice-affecting, 36 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 36, Nonsense Mutation 5, Frame Shift Del 2, Splice Site 2, In Frame Ins 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- THSD7B | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 24/125 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV55689123, COSV55699747; called by muse, mutect2, varscan2
- TP53 | c.470_475dup p.V157_R158dup | In Frame Ins (INS) | VAF 20/31 reads (65%) | hotspot (GDC flag); catalogued as rs1555526140; ClinVar: uncertain significance; called by mutect2, varscan2
- AC098582.1 | c.1847A>T p.E616V | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52020436; called by muse, mutect2, varscan2
- AEBP1 | c.1278C>A p.D426E | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.555); catalogued as COSV56258094; called by muse, mutect2, varscan2
- AIRE | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs376901046, CM162783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD13C | c.1309G>C p.G437R | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52031917; called by muse, mutect2, varscan2
- AQP1 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV61266810, COSV61267959, COSV61268717; called by muse, mutect2
- AQP4 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV67218713; called by muse, mutect2, varscan2
- ARSI | c.1271G>A p.W424* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV60816889; called by muse, mutect2, varscan2
- ATP10A | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.031); catalogued as rs1398816768, COSV63517642; called by muse, mutect2, varscan2
- ATP2A1 | c.2369T>C p.V790A | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV62869522; called by muse, mutect2, varscan2
- ATXN7 | c.1506G>T p.E502D | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as COSV55751218; called by muse, mutect2, varscan2
- BACH1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV54519051; called by muse, mutect2, varscan2
- BAZ1B | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 112/211 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59991367; called by muse, mutect2, varscan2
- CBR4 | c.401-1G>C p.X134_splice | Splice Site (SNP) | VAF 17/39 reads (44%) | catalogued as COSV60370161; called by mutect2, varscan2
- CC2D2A | c.4622A>G p.D1541G | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV58011388; called by muse, mutect2
- CCDC57 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58935244; called by muse, mutect2, varscan2
- COL16A1 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54706458; called by muse, mutect2, varscan2
- COLGALT2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768723326, COSV62727701; called by muse, mutect2, varscan2
- CPSF1 | c.2078C>G p.S693C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV58233652; called by muse, mutect2, varscan2
- CR1 | c.5354A>T p.H1785L | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV65458408; called by muse, mutect2, varscan2
- CTDSPL2 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52946257; called by muse, mutect2, varscan2
- CYLC1 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs201228346, COSV61412329; called by muse, mutect2, varscan2
- DDX46 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV62799415; called by muse, mutect2, varscan2
- DLL3 | c.1004C>G p.S335C | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52694806; called by muse, mutect2, varscan2
- ELP1 | c.2701G>C p.D901H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65897847; called by muse, mutect2, varscan2
- EMB | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as rs866302109, COSV57482353; called by muse, mutect2, varscan2
- EPN2 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs766973140, COSV59061306; called by muse, mutect2, varscan2
- ERC1 | c.900G>C p.Q300H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as COSV61695131; called by muse, mutect2, varscan2
- ESPL1 | c.1883A>T p.H628L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV57759665; called by muse, mutect2, varscan2
- FAT4 | c.7690G>A p.A2564T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.374); catalogued as rs866065315, COSV58686731; called by muse, mutect2
- FAT4 | c.9463G>C p.D3155H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58686746; called by muse, mutect2, varscan2
- FREM2 | c.4111A>G p.T1371A | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54838679; called by muse, mutect2, varscan2
- GABBR1 | c.2058G>T p.W686C | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63542592; called by muse, mutect2, varscan2
- GALNTL5 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 108/158 reads (68%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV67180208; called by muse, mutect2, varscan2
- GSK3B | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as rs201787969, COSV51775499; called by mutect2, varscan2
- GTF2IRD2 | c.1426C>A p.Q476K | Missense Mutation (SNP) | VAF 84/1795 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.167); catalogued as COSV63100367; called by muse, mutect2
- HDGFL1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57752013; called by muse, mutect2, varscan2
- HERC2 | c.6910A>T p.K2304* | Nonsense Mutation (SNP) | VAF 148/760 reads (19%) | catalogued as COSV55324734; called by muse, mutect2, varscan2
- HLA-DPB1 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV101330953, COSV69603243; called by muse, mutect2
- HPS5 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772160206, COSV56378344; called by muse, mutect2, varscan2
- HSPA1L | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1385211232, COSV65149060; called by muse, mutect2, varscan2
- IGSF11 | c.112C>A p.Q38K (on ENST00000393775 / NM_001015887.3; = p.Q37K on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV61170250; called by muse, mutect2
- INSL5 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV58788272; called by muse, mutect2, varscan2
- KIF26B | c.6097G>A p.A2033T | Missense Mutation (SNP) | VAF 64/85 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs996759727, COSV63641982; called by muse, mutect2, varscan2
- KLHL18 | c.452T>C p.M151T | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.183); catalogued as rs1369023783, COSV51745824; called by muse, mutect2, varscan2
- KRT35 | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as COSV55843146; called by muse, mutect2
- LALBA | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV56395971; called by muse, mutect2, varscan2
- LCOR | c.3473G>A p.C1158Y | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as COSV53716117; called by muse, mutect2, varscan2
- LRP1B | c.8420A>C p.E2807A | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.253); catalogued as COSV67222665; called by muse, mutect2, varscan2
- MAP1S | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60722790; called by muse, mutect2, varscan2
- MAP9 | c.708G>T p.E236D | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV60904801; called by muse, mutect2, varscan2
- MRC2 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57640038; called by muse, mutect2, varscan2
- MTOR | c.7501A>T p.I2501F | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV63871874; called by muse, mutect2
- MYO1E | c.2476C>T p.L826F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs746479279, COSV55687801; called by muse, mutect2, varscan2
- MYORG | c.1659G>T p.M553I | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV52627238; called by muse, mutect2, varscan2
- NCOA2 | c.3841G>A p.G1281S | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.966); catalogued as COSV51219671; called by muse, mutect2, varscan2
- NLRC4 | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.103); catalogued as COSV100707231, COSV61592804; called by muse, mutect2, varscan2
- NPSR1 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs267601495, COSV62200834, COSV62202076; called by muse, mutect2, varscan2
- OPN5 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV55245617; called by muse, mutect2
- OR2L8 | c.455C>A p.S152* | Nonsense Mutation (SNP) | VAF 104/488 reads (21%) | catalogued as COSV61726895; called by muse, varscan2
- OR2T33 | c.431T>C p.M144T | Missense Mutation (SNP) | VAF 153/546 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV58815542; called by muse, mutect2, varscan2
- OR4A16 | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV59043234; called by muse, mutect2, varscan2
- OR8H2 | c.196C>A p.H66N | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.178); catalogued as COSV57944790, COSV57945198; called by muse, mutect2, varscan2
- OR9A2 | c.65T>G p.L22R | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV63306612; called by muse, mutect2, varscan2
- OXSM | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV55001656; called by muse, mutect2, varscan2
- PBX1 | c.953C>A p.A318D | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100905308, COSV63343818; called by muse, mutect2, varscan2
- PDCD2L | c.1021C>G p.P341A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as COSV55825425; called by muse, mutect2, varscan2
- PHC3 | c.1597C>G p.Q533E (on ENST00000494943 / NM_001308116.2; = p.Q545E on NM_024947.4) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.68); catalogued as COSV71948748; called by muse, mutect2, varscan2
- PI4KA | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs542084506, COSV55411568; called by muse, mutect2, varscan2
- PIWIL4 | c.2348C>A p.T783N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54409429; called by muse, mutect2, varscan2
- PPARGC1A | c.1781G>T p.R594I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV53527797; called by muse, mutect2, varscan2
- PRDM7 | c.1169G>C p.S390T | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.014); catalogued as COSV57986768; called by muse, mutect2, varscan2
- PRKCQ | c.137T>A p.I46N | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV54111876; called by muse, mutect2, varscan2
- PTDSS1 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61264823; called by muse, mutect2, varscan2
- PTPRB | c.3604G>C p.D1202H | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV54241475; called by muse, mutect2, varscan2
- PTPRB | c.1132G>C p.D378H | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.653); catalogued as COSV54241493; called by muse, mutect2, varscan2
- SEMA3D | c.587C>A p.T196K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV52393994; called by muse, mutect2, varscan2
- SGSM2 | c.2828C>T p.S943L (on ENST00000426855 / NM_001098509.2; = p.S988L on NM_014853.3) | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756175700, COSV51512097; called by muse, mutect2, varscan2
- SLC13A4 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.424); catalogued as COSV62461187; called by muse, mutect2, varscan2
- SLC18A1 | c.1337C>A p.S446Y | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52348259; called by muse, mutect2, varscan2
- SLC25A23 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV51191742; called by muse, mutect2, varscan2
- SLC7A2 | c.1685C>A p.P562Q (on ENST00000494857 / NM_001370338.1; = p.P601Q on NM_003046.6) | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50253980; called by muse, mutect2, varscan2
- SLCO2A1 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV60486082; called by muse, mutect2, varscan2
- SLF1 | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV54370134; called by muse, mutect2, varscan2
- SMCR8 | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV58177586; called by muse, mutect2, varscan2
- SPAG7 | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 139/182 reads (76%) | SIFT tolerated (0.78); PolyPhen benign (0.092); catalogued as COSV52777513; called by muse, mutect2, varscan2
- SPAM1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56144132; called by muse, mutect2, varscan2
- SPIRE2 | c.1121G>T p.C374F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV65555880; called by muse, mutect2, varscan2
- SUPT20H | c.193G>A p.E65K (on ENST00000350612 / NM_001014286.3; = p.E66K on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62247984; called by muse, mutect2, varscan2
- TCF20 | c.3322G>C p.V1108L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV59491578; called by muse, mutect2, varscan2
- TOP2B | c.2656C>T p.P886S (on ENST00000264331 / NM_001330700.2; = p.P881S on NM_001068.3) | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV51968269; called by muse, mutect2, varscan2
- TPH1 | c.471-1G>C p.X157_splice | Splice Site (SNP) | VAF 16/59 reads (27%) | catalogued as COSV51458276; called by muse, mutect2, varscan2
- TSEN34 | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV55475866; called by muse, mutect2, varscan2
- TTN | c.20677G>A p.V6893M (on ENST00000591111; = p.V5966M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | PolyPhen benign (0.23); catalogued as COSV60081143; called by muse, mutect2, varscan2
- TVP23C | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.241); catalogued as COSV56670174; called by muse, mutect2, varscan2
- TYRO3 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV55483358; called by muse, mutect2, varscan2
- UBE2Q1 | c.471T>G p.C157W | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV52725199, COSV99427769; called by muse, mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as rs747493460; called by mutect2, varscan2
- ZC3H3 | c.2147C>A p.P716H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52790002, COSV52790053; called by muse, mutect2, varscan2
- ZMYM4 | c.2005C>T p.L669F | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.976); catalogued as COSV58910986; called by muse, mutect2, varscan2
- ZNF227 | c.1273A>T p.I425F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as COSV57312440; called by muse, mutect2, varscan2
- ZSWIM4 | c.989G>T p.C330F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV99584938; called by muse, mutect2
- FZD9 | c.913_915dup p.Q305dup | In Frame Ins (INS) | VAF 18/94 reads (19%) | called by mutect2, varscan2
- OPRL1 | c.631_638del p.W211Gfs*111 | Frame Shift Del (DEL) | VAF 37/242 reads (15%) | called by mutect2, varscan2
- PCDH7 | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA8 | c.3987G>A p.A1329= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as rs1365443017, COSV52195658; called by muse, mutect2, varscan2
- AC109583.1 | c.693C>T p.D231= | Silent (SNP) | VAF 57/82 reads (70%) | catalogued as COSV58405780; called by muse, mutect2, varscan2
- AJAP1 | c.573C>G p.A191= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV65450881; called by muse, varscan2
- APOC3 | c.69C>T p.A23= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs372158089; called by muse, mutect2, varscan2
- CDKL5 | c.1755G>A p.L585= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as rs779156340, COSV66111382; called by muse, mutect2, varscan2
- CNTNAP3 | c.1839C>A p.G613= | Silent (SNP) | VAF 104/529 reads (20%) | catalogued as COSV52668235, COSV52676585; called by muse, mutect2, varscan2
- COL8A2 | c.39G>A p.L13= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV57441856; called by muse, varscan2
- DIAPH3 | c.2136T>G p.L712= (on ENST00000400324 / NM_001042517.2; = p.L449= on NM_030932.3) | Silent (SNP) | VAF 47/221 reads (21%) | catalogued as COSV57370944; called by muse, mutect2, varscan2
- DNAJB8 | c.190C>T p.L64= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV59878764; called by muse, mutect2, varscan2
- DSN1 | c.957G>A p.Q319= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1405453170, COSV65519243; called by muse, mutect2, varscan2
- EYA1 | c.405C>A p.G135= | Silent (SNP) | VAF 38/270 reads (14%) | catalogued as CD972191, COSV58163359; called by muse, mutect2, varscan2
- FMR1NB | c.363A>C p.A121= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as COSV63272799; called by muse, mutect2
- GLIPR1 | c.327T>A p.S109= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as COSV56991091; called by muse, mutect2, varscan2
- GRAMD2B | c.21T>C p.D7= | Silent (SNP) | VAF 56/104 reads (54%) | catalogued as COSV53507671; called by muse, mutect2, varscan2
- GRHL1 | c.1449G>A p.Q483= | Silent (SNP) | VAF 59/148 reads (40%) | catalogued as rs1325996302, COSV61408361; called by muse, mutect2, varscan2
- H2BC5 | c.198C>T p.F66= | Silent (SNP) | VAF 25/185 reads (14%) | catalogued as rs769305558, COSV56801251; called by muse, mutect2, varscan2
- ITGBL1 | c.1380T>G p.G460= | Silent (SNP) | VAF 47/195 reads (24%) | catalogued as COSV66008268; called by muse, mutect2, varscan2
- KLHL9 | c.571C>T p.L191= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV62921338; called by muse, mutect2, varscan2
- MAP3K5 | c.3027T>C p.D1009= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV62889263; called by muse, mutect2, varscan2
- MST1R | c.1338A>G p.V446= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV56569061; called by muse, mutect2, varscan2
- NEB | c.1620C>G p.P540= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as rs776014034, COSV51419153; called by muse, mutect2, varscan2
- OBSCN | c.15441C>T p.C5147= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as rs753088901, COSV52756433; called by muse, mutect2, varscan2
- PCLO | c.7003T>C p.L2335= | Silent (SNP) | VAF 77/334 reads (23%) | catalogued as COSV61636795; called by muse, mutect2, varscan2
- PHF21A | c.1002A>G p.K334= (on ENST00000418153 / NM_001101802.3; = p.K335= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 181/377 reads (48%) | catalogued as COSV57654141; called by muse, mutect2, varscan2
- PLXND1 | c.1869C>T p.I623= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV60713874; called by muse, mutect2, varscan2
- PPIL1 | c.297A>G p.A99= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as rs756837992, COSV65472591; called by muse, mutect2, varscan2
- PPP2R1B | c.1134A>G p.L378= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1565459542, COSV59535664; called by muse, mutect2, varscan2
- PRICKLE2 | c.2572C>A p.R858= (on ENST00000295902; = p.R802= on NM_198859.4) | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV55766527, COSV55768056; called by muse, mutect2, varscan2
- RNF17 | c.3855C>T p.P1285= | Silent (SNP) | VAF 24/186 reads (13%) | catalogued as COSV55040903; called by muse, mutect2, varscan2
- SH3GL2 | c.1032G>A p.V344= | Silent (SNP) | VAF 54/246 reads (22%) | catalogued as rs371297260; called by muse, mutect2, varscan2
- SRGAP1 | c.2061C>T p.I687= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as COSV61898369; called by muse, mutect2, varscan2
- TDRD5 | c.2238T>A p.P746= | Silent (SNP) | VAF 43/73 reads (59%) | catalogued as COSV54243329; called by muse, mutect2, varscan2
- TMCO5A | c.144G>A p.L48= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV60464853; called by muse, mutect2
- TOP3A | c.1650C>T p.Y550= | Silent (SNP) | VAF 75/154 reads (49%) | catalogued as rs759705124, COSV58177584; called by muse, mutect2, varscan2
- TTN | c.1296C>G p.A432= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV60081203; called by muse, mutect2, varscan2
- ZNF578 | c.453T>A p.P151= | Silent (SNP) | VAF 47/157 reads (30%) | catalogued as COSV69736549; called by muse, mutect2, varscan2
- CCDC62 | c.*76C>T | 3'UTR (SNP) | VAF 40/93 reads (43%) | catalogued as rs771310488, COSV99457188; called by muse, mutect2, varscan2
- MOCS2 | c.-640G>A | 5'UTR (SNP) | VAF 17/41 reads (41%) | catalogued as rs1021202508, COSV63740913; called by muse, mutect2, varscan2
